Surgical pathology report (de-identified scan), TCGA case TCGA-VS-A8EG, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VS-A8EG-01A (Primary Tumor).

Collect date: (MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Cervix

- "Biopsy of cervix":

Squamous cell carcinoma with glandular extension (see note).

Note: In this sample is not possible to assess the presence of invasion.

ICD O-3

Carcinoma, squamous cell
NOS 8070/3

Site: Cervix NOS C53.9

Jan 11/21/13

Criteria	AW 10/21/13	Yes	No
Diagnostic Discrepancy			
HIF-1A Discrepancy			
Case is (curable)			

Source: NCI Genomic Data Commons file aa097fde-e247-4665-a936-449f7d0cf342 (TCGA-VS-A8EG.96C32FDF-692D-4709-B1A7-E5B22318E683.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).